Somatic mutation profile of tumor specimen C3L-01061-01 (aliquot CPT0217710011) from CPTAC case C3L-01061, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.2 years (24,196 days).
Specimen C3L-01061-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbb6e554-28b6-4d37-9204-9ef7f4676317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01061-31 (Blood Derived Normal), aliquot CPT0220160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f41fd95-8046-433a-b40b-19865cb58e56

The open-access MAF lists 75 somatic variants for this specimen: 51 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Intron 4, RNA 2, In Frame Del 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR1A | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 266/309 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760845113, COSV64024527; called by muse, mutect2, varscan2
- ADAMDEC1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs753899251, COSV56474101; called by muse, mutect2, varscan2
- ARL11 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as rs994780789, COSV56290713; called by muse, mutect2, varscan2
- CACNA1H | c.5548G>A p.V1850M | Missense Mutation (SNP) | VAF 217/256 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986566182, COSV52357189; called by muse, mutect2, varscan2
- CASZ1 | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100681525; called by muse, mutect2, varscan2
- CPO | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs368297452, COSV55941035; called by muse, mutect2, varscan2
- DNAH11 | c.11579C>G p.S3860C | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV60957917; called by muse, mutect2, varscan2
- FAM200A | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs187969464; called by muse, mutect2, varscan2
- FRMD5 | c.1196A>C p.D399A | Missense Mutation (SNP) | VAF 168/351 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs368308860; called by muse, mutect2, varscan2
- HEYL | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs141784681; called by muse, mutect2, varscan2
- KCNC2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 319/704 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1293921948, COSV54369809; called by muse, mutect2, varscan2
- KCNJ12 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 96/1088 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs41284970; called by muse, mutect2
- KLKB1 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 131/338 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs1372696539, COSV99250160; called by muse, mutect2, varscan2
- LOXHD1 | c.2726C>T p.T909M | Missense Mutation (SNP) | VAF 236/540 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs974335083; called by muse, mutect2, varscan2
- MS4A6E | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 118/253 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as rs955579804, COSV100279031; called by muse, mutect2
- MUC3A | c.8687G>A p.S2896N | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as rs749248594; called by muse, mutect2
- ONECUT2 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 230/494 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449358331, COSV72153018; called by muse, mutect2, varscan2
- OR11G2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 128/279 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs373138732; called by muse, mutect2, varscan2
- PEX2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV63813845; called by muse, mutect2, varscan2
- PRAMEF20 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 462/1087 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs1442183853; called by muse, mutect2, varscan2
- RDH8 | c.710G>A p.R237Q (on ENST00000651512; = p.R217Q on NM_015725.4) | Missense Mutation (SNP) | VAF 196/470 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs769546527, COSV50675987; called by muse, mutect2, varscan2
- RFPL2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs778808289, COSV99963904; called by muse, mutect2, varscan2
- SLC24A1 | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 252/557 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56051292; called by muse, mutect2, varscan2
- SLC6A14 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 84/97 reads (87%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782404299, COSV64141364; called by muse, mutect2, varscan2
- TAL2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748538341, COSV100482515, COSV61883785; called by muse, mutect2, varscan2
- TCHH | c.4961G>A p.R1654H | Missense Mutation (SNP) | VAF 277/600 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.662); catalogued as rs775186687, COSV100914909; called by muse, mutect2, varscan2
- TLL2 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs746988385; called by muse, mutect2, varscan2
- TRPM2 | c.4489G>A p.A1497T | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1292816882, COSV55967042; called by muse, mutect2
- UGT1A3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs540607993, COSV59387847; called by muse, mutect2, varscan2
- UGT1A6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 95/210 reads (45%) | catalogued as rs571650145, COSV59382336, COSV59396376; called by muse, mutect2, varscan2
- ADPRHL1 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 169/333 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATXN1L | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 184/212 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- DACT2 | c.1257C>G p.S419R | Missense Mutation (SNP) | VAF 101/115 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DNAJB6 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 311/1092 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- FDPS | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- HECTD1 | c.3401A>T p.N1134I | Missense Mutation (SNP) | VAF 134/317 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- HMCN1 | c.6379A>T p.S2127C | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KMT2C | c.4282G>T p.D1428Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KRTAP4-6 | c.36C>G p.D12E | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT tolerated (0.71); called by muse, mutect2, varscan2
- NLRP11 | c.2786T>C p.L929S | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR52E4 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF20 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 355/843 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR12 | c.2315C>T p.A772V (on ENST00000615927; = p.A1593V on NM_020719.3) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PTEN | c.42_44del p.R15del | In Frame Del (DEL) | VAF 196/238 reads (82%) | called by mutect2, pindel, varscan2
- SERPINA3 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SF3B2 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- SI | c.4457C>A p.T1486K | Missense Mutation (SNP) | VAF 171/410 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TH | c.1525T>A p.S509T (on ENST00000381178 / NM_199292.3; = p.S478T on NM_000360.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- USP33 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- USP38 | c.238_240del p.F80del | In Frame Del (DEL) | VAF 107/257 reads (42%) | called by pindel, varscan2
- ARHGAP45 | c.2097G>A p.A699= | Silent (SNP) | VAF 36/438 reads (8%) | catalogued as rs747616734, COSV57432246; called by muse, mutect2
- CFAP77 | c.450C>T p.H150= | Silent (SNP) | VAF 149/309 reads (48%) | catalogued as rs759081377, COSV58014883; called by muse, mutect2, varscan2
- CUX2 | c.4278C>T p.G1426= | Silent (SNP) | VAF 149/309 reads (48%) | catalogued as rs551398013; called by muse, mutect2, varscan2
- F13A1 | c.543G>A p.T181= | Silent (SNP) | VAF 186/435 reads (43%) | catalogued as rs747128938, COSV53553981; called by muse, mutect2, varscan2
- KSR2 | c.1626G>A p.P542= | Silent (SNP) | VAF 98/198 reads (49%) | catalogued as rs377054023; called by muse, mutect2, varscan2
- LRGUK | c.2250G>A p.P750= | Silent (SNP) | VAF 111/431 reads (26%) | catalogued as rs747802104; called by muse, mutect2, varscan2
- LRP6 | c.1677T>C p.H559= | Silent (SNP) | VAF 184/396 reads (46%) | called by muse, mutect2, varscan2
- MPP2 | c.513C>T p.A171= (on ENST00000461854 / NM_001278372.2; = p.A147= on NM_005374.5) | Silent (SNP) | VAF 217/506 reads (43%) | catalogued as rs753192544; called by muse, mutect2, varscan2
- PCDHA5 | c.1884C>T p.G628= | Silent (SNP) | VAF 253/597 reads (42%) | catalogued as rs1562273954, COSV65349721; called by muse, mutect2, varscan2
- RARB | c.168G>A p.P56= | Silent (SNP) | VAF 92/210 reads (44%) | catalogued as rs368324313; called by muse, mutect2, varscan2
- SHANK2 | c.2205G>A p.P735= | Silent (SNP) | VAF 116/250 reads (46%) | catalogued as rs367733874; called by mutect2, varscan2
- SLC32A1 | c.660G>A p.L220= | Silent (SNP) | VAF 247/539 reads (46%) | called by muse, mutect2, varscan2
- SLC35G4 | c.471C>T p.Y157= | Silent (SNP) | VAF 158/502 reads (31%) | catalogued as rs574851637; called by muse, mutect2
- SLC39A5 | c.834C>T p.G278= | Silent (SNP) | VAF 125/275 reads (45%) | catalogued as rs761896583; called by muse, mutect2, varscan2
- SPATA31A6 | c.3666G>A p.A1222= | Silent (SNP) | VAF 546/1208 reads (45%) | catalogued as rs770338146; called by muse, varscan2
- TNFRSF11A | c.1758G>A p.P586= | Silent (SNP) | VAF 132/272 reads (49%) | called by muse, mutect2, varscan2
- ZNF462 | c.42G>A p.P14= | Silent (SNP) | VAF 146/328 reads (45%) | catalogued as rs146521601; called by muse, mutect2, varscan2
- ALDH1A3 | c.99+34G>A | Intron (SNP) | VAF 66/151 reads (44%) | catalogued as rs1159656263; called by muse, mutect2, varscan2
- ANKS6 | c.*3961C>T | 3'UTR (SNP) | VAF 153/362 reads (42%) | catalogued as rs1380153337; called by muse, mutect2, varscan2
- CORO1A | c.756+35G>A | Intron (SNP) | VAF 193/238 reads (81%) | called by muse, mutect2, varscan2
- DCHS2 | n.784T>C | RNA (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2676T>G | Intron (SNP) | VAF 140/344 reads (41%) | called by muse, mutect2, varscan2
- OR2W5 | n.1066C>T | RNA (SNP) | VAF 124/239 reads (52%) | catalogued as rs562602532; called by muse, mutect2, varscan2
- TFCP2 | c.123-6141C>T | Intron (SNP) | VAF 40/638 reads (6%) | catalogued as rs1339931447; called by muse, mutect2
